Surgical pathology report (de-identified scan), TCGA case TCGA-IS-A3K6, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-IS-A3K6-01A (Primary Tumor).

[page 1 of 3]
```

1: SP: Uterus, cervix, bilateral tubes ovaries (fs) (
2: SP: Tumor from surface of uterus (fs) (
3: SP: Right external iliac lymph node
4: SP: Right internal iliac lymph node
5: SP: Right hypogastric lymph node
6: SP: Right obturator lymph node (
7: SP: Left hypogastric lymph node
8: SP: Left external iliac lymph nodes
9: SP: Left obturator lymph node (

```

- 1) UTERUS, BILATERAL FALLOPIAN TUBES AND OVARIES, EXCISION:
- HIGH GRADE, ANAPLASTIC UTERINE LEIOMYOSARCOMA, TWO FOCI, MEASURING 8.5 CM AND 6.5 CM, INVOLVING UTERINE CORPUS (SEE NOTE). VASCULAR INVASION IS SEEN.
- BENIGN ECTOCERVIX AND ENDOCERVIX. ATROPHIC ENDOMETRIUM. INTRAMURAL AND SUBMUCOSAL LEIOMYOMATA. BENIGN ATROPHIC OVARIES AND UNREMARKABLE FALLOPIAN TUBES.
- 2) TUMOR FROM SURFACE OF UTERUS, BIOPSY:
- HIGH GRADE ANAPLASTIC LEIOMYOSARCOMA.
- 3) LYMPH NODE, RIGHT EXTERNAL ILIAC, EXCISION:
- SEVEN BENIGN LYMPH NODES (0/7).
- 4) LYMPH NODE, RIGHT INTERNAL ILIAC, EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 5) LYMPH NODES, RIGHT HYPOGASTRIC, EXCISION:
- BENIGN PREDOMINANTLY FATTY, SOFT TISSUE. NO LYMPH NODE IDENTIFIED.
- 6) LYMPH NODE, RIGHT OBTURATOR, EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 7) LYMPH NODE, LEFT HYPOGASTRIC, EXCISION:
- SIX BENIGN LYMPH NODE (0/6).
- 8) LYMPH NODE, LEFT EXTERNAL ILIAC, EXCISION:

** Continued on next page **

ICD-0-3

leiomyosarcoma, Nos 8890/3
Site: uterus, Nos C55-9

stIPAA Discrepancy		
	461 62-13044	

[page 2 of 3]
- SIX BENIGN LYMPH NODES (0/6).

- 9) LYMPH NODE, LEFT OBTURATOR, EXCISION:
- TWO BENIGN LYMPH NODES (0/2).

NOTE: IMMUNOHISTOCHEMICAL STUDIES SHOW THAT THE TUMOR CELLS ARE POSITIVE FOR SMOOTH MUSCLE ACTIN, AND NEGATIVE FOR CYTOKERATINS (AE1:AE3 CAM5.2); SUPPORTING THE ABOVE DIAGNOSIS.

** Report Electronically Signed Out **

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 3 of 3]
ADDENDUM:

** SIGNED OUT [REDACTED] **

ADDENDUM REPORT
[REDACTED]

#1. UTERUS

THE SLIDES FROM THE PRIOR BONE BIOPSY [REDACTED] WERE REVIEWED. THE CURRENT UTERINE TUMOR AND THE BONE LESION SHARE SIMILAR HISTOLOGIC FEATURES, AND ARE BOTH POSITIVE FOR 013 BY IMMUNOHISTOCHEMISTRY. CONSIDERING THE ENTIRE CLINICAL AND PATHOLOGIC FINDINGS, THE BONE LESION MOST LIKELY REPRESENTS METASTASIS FROM THE UTERINE LEIOMYOSARCOMA, DESPITE AN UNUSUAL HISTOLOGIC APPEARANCE AND THE PARADOXICAL EXPRESSION OF 013 BY IMMUNOHISTOCHEMICAL STAIN.

CASE DISCUSSED WITH [REDACTED]
[REDACTED]

** Report Electronically Signed Out **

** End of Report **

PATH
REPORT
11

Source: NCI Genomic Data Commons file 1b015741-c8d9-4266-85e7-0cae641cc0aa (TCGA-IS-A3K6.152BA80C-10DA-4B35-A524-305C4FDBAEB2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).